Somatic mutation profile of tumor specimen TCGA-VF-A8AC-01A (aliquot TCGA-VF-A8AC-01A-11D-A435-10) from TCGA case TCGA-VF-A8AC, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 29.0 years (10,598 days).
Specimen TCGA-VF-A8AC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2c483cf-3072-4a5b-8603-a35702584d8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VF-A8AC-10A (Blood Derived Normal), aliquot TCGA-VF-A8AC-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1680d814-1e1c-41f5-94fc-f8830b738030

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 2, Silent 1, 3'UTR 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 118/315 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCAR1 | c.2284G>C p.E762Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56269659; called by muse, mutect2, varscan2
- ESRP1 | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as rs1402440040; called by muse, mutect2
- ACAD10 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CES3 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CRMP1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DDHD1 | c.1654+2T>C p.X552_splice (on ENST00000323669; = p.X749_splice on NM_030637.3) | Splice Site (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- MTFR1 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TKTL1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- ZNF540 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- ZNF615 | c.1976A>C p.K659T | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- FAF2 | c.54G>A p.L18= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-9371_15832-9342del | Intron (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- NIBAN3 | c.1540-31T>A | Intron (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- WSCD2 | c.*2G>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | catalogued as rs939865110; called by muse, mutect2
